Somatic mutation profile of tumor specimen TCGA-13-1495-01A (aliquot TCGA-13-1495-01A-01W-0545-08) from TCGA case TCGA-13-1495, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.4 years (22,046 days).
Specimen TCGA-13-1495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 970e164c-119a-4834-b649-bc1f37934ff1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1495-10A (Blood Derived Normal), aliquot TCGA-13-1495-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da0d3ac3-9477-4fcf-9b55-71027fad2338

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 17, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 285/353 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53894996; called by muse, mutect2, varscan2
- ADGRF3 | c.2908G>C p.G970R (on ENST00000311519 / NM_001145168.1; = p.G771R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1411343250, COSV61051018; called by muse, mutect2, varscan2
- AHNAK | c.3199A>G p.M1067V | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV57217447; called by muse, mutect2, varscan2
- AKR1C1 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV66499325; called by muse, mutect2, varscan2
- AMER1 | c.1570T>A p.C524S | Missense Mutation (SNP) | VAF 83/769 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV57662307, COSV57665081; called by muse, mutect2, varscan2
- ATP13A1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs371113170, COSV52285212; called by muse, mutect2, varscan2
- CDK12 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 251/318 reads (79%) | catalogued as COSV71001257; called by muse, mutect2, varscan2
- CHPF2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375493278; called by mutect2, varscan2
- CNTN6 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 66/830 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100610454; called by muse, mutect2
- CPXCR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52160939; called by muse, mutect2, varscan2
- EPHB6 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 47/592 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101235962; called by muse, mutect2
- FABP7 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 15/429 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs1372084043, COSV100737930, COSV100737994; called by muse, mutect2
- FCRL2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs764455952, COSV63833959, COSV63834941; called by muse, mutect2, varscan2
- FMO5 | c.1093A>C p.T365P | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54207703; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs752075537; called by mutect2, varscan2
- HERC2 | c.6647G>A p.R2216H | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763055552, COSV55328512; called by muse, mutect2, varscan2
- LRRC3B | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV67521526; called by muse, mutect2, varscan2
- MECOM | c.860A>T p.H287L (on ENST00000468789 / NM_001105078.4; = p.H475L on NM_004991.4) | Missense Mutation (SNP) | VAF 82/765 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52961682, COSV52966955; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | catalogued as rs773403681; called by mutect2, varscan2
- PDPN | c.259G>C p.E87Q (on ENST00000621990; = p.E163Q on NM_006474.4) | Missense Mutation (SNP) | VAF 57/502 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.912); catalogued as COSV53848756; called by muse, mutect2, varscan2
- PEX2 | c.406A>T p.K136* | Nonsense Mutation (SNP) | VAF 32/194 reads (16%) | catalogued as COSV63813777; called by muse, mutect2, varscan2
- PPARGC1A | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 259/401 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as rs146256421; called by muse, mutect2, varscan2
- SI | c.3050C>A p.T1017N | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52284164; called by muse, mutect2, varscan2
- SYCP1 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV101050863; called by muse, mutect2
- SYT3 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); catalogued as rs376869372, COSV58897355; called by muse, mutect2, varscan2
- TARS2 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 112/1985 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs748946128, COSV100945916; called by muse, mutect2
- TBXT | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51618647; called by muse, mutect2, varscan2
- TTN | c.36386C>T p.T12129M (on ENST00000591111; = p.T4705M on NM_003319.4) | Missense Mutation (SNP) | VAF 134/314 reads (43%) | PolyPhen benign (0.367); catalogued as rs774214497, COSV100603982, COSV60068917, COSV60075249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR7 | c.1456A>C p.I486L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as COSV54355736; called by muse, mutect2, varscan2
- ZNF43 | c.2340T>G p.H780Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61684397; called by muse, mutect2, varscan2
- ZNF473 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 103/221 reads (47%) | catalogued as rs1422510071, COSV54523862; called by muse, mutect2, varscan2
- ZSWIM4 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.41); catalogued as COSV54323137; called by muse, mutect2, varscan2
- APOB | c.2421G>T p.Q807H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2
- BCDIN3D | c.600del p.W200* | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | called by mutect2, pindel, varscan2
- HOXB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COMT | c.294G>A p.K98= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV52890138; called by muse, mutect2, varscan2
- CRNKL1 | c.552G>A p.P184= | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as rs367820186; called by muse, mutect2, varscan2
- DLK1 | c.282G>A p.S94= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1250410292; called by muse, mutect2, varscan2
- EPB41 | c.2397C>T p.T799= (on ENST00000343067 / NM_001166005.2; = p.T590= on NM_203342.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV58046408; called by muse, mutect2
- FRMD3 | c.402G>A p.R134= | Silent (SNP) | VAF 66/300 reads (22%) | catalogued as COSV58463551; called by muse, mutect2, varscan2
- GAPDHS | c.915C>T p.F305= | Silent (SNP) | VAF 76/499 reads (15%) | called by muse, mutect2, varscan2
- HLA-DPB1 | c.31C>A p.R11= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV69603395; called by muse, mutect2, varscan2
- HSPA12A | c.1572C>T p.D524= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65022707; called by muse, mutect2, varscan2
- KCNA1 | c.1005C>T p.I335= | Silent (SNP) | VAF 58/392 reads (15%) | catalogued as rs760445014, COSV66836473; called by muse, mutect2, varscan2
- RBMX2 | c.231A>G p.K77= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV59729442; called by mutect2, varscan2
- SEC31A | c.2409G>A p.P803= (on ENST00000355196 / NM_001318120.1; = p.P764= on NM_016211.4) | Silent (SNP) | VAF 71/173 reads (41%) | catalogued as rs145039719; called by muse, mutect2, varscan2
- SKA3 | c.66G>A p.T22= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs746308159, COSV53435235; called by muse, mutect2, varscan2
- SPINT2 | c.327T>C p.S109= | Silent (SNP) | VAF 23/438 reads (5%) | catalogued as COSV100007497; called by muse, mutect2
- TPI1 | c.819C>G p.S273= (on ENST00000229270; = p.S236= on NM_000365.6) | Silent (SNP) | VAF 14/335 reads (4%) | catalogued as COSV99222840; called by muse, mutect2
- TRIM7 | c.690G>A p.Q230= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs200756291, COSV51243859; called by muse, mutect2, varscan2
- UFSP1 | c.132C>T p.H44= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs769776481; called by muse, mutect2, varscan2
- ZNF33A | c.1506G>C p.G502= (on ENST00000458705 / NM_006974.3; = p.G503= on NM_006954.2) | Silent (SNP) | VAF 45/245 reads (18%) | catalogued as COSV56725901; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154338 C>A | 3'Flank (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- DCHS2 | n.5070G>C | RNA (SNP) | VAF 27/68 reads (40%) | catalogued as COSV61773925; called by muse, mutect2, varscan2
